Somatic mutation profile of tumor specimen TCGA-AA-3489-01A (aliquot TCGA-AA-3489-01A-21D-1835-10) from TCGA case TCGA-AA-3489, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 75.6 years (27,606 days).
Specimen TCGA-AA-3489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c35fda6f-cadf-40d4-ae5c-90623826b1a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3489-11A (Solid Tissue Normal), aliquot TCGA-AA-3489-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b37d1fe5-b9fb-40e4-b98f-02080a6d289e

The open-access MAF lists 102 somatic variants for this specimen: 79 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 20, Nonsense Mutation 8, Frame Shift Ins 3, Splice Site 3, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4175C>A p.S1392* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs786204170, CM960068, CM990162, COSV57326586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3339+2T>G p.X1113_splice | Splice Site (SNP) | VAF 13/94 reads (14%) | catalogued as COSV100229526; called by muse, mutect2, varscan2
- ABCA13 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.603); catalogued as COSV101330193; called by muse, mutect2, varscan2
- ABCA6 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV52639117; called by muse, mutect2, varscan2
- ADAMTS3 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs773642539, COSV54392291; called by muse, mutect2, varscan2
- ADGRV1 | c.6968T>A p.L2323Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101316570; called by muse, mutect2, varscan2
- APOB | c.9764T>A p.V3255D | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99268294; called by muse, mutect2, varscan2
- ATP6V1A | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs752561873, COSV99850423; called by muse, varscan2
- ATRN | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs767305834, COSV53524459; called by muse, mutect2, varscan2
- BCL9L | c.412+2T>C p.X138_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100600238; called by muse, mutect2
- CASP8 | c.24T>A p.Y8* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV51851417; called by muse, mutect2, varscan2
- CCDC125 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as COSV67288131; called by muse, mutect2, varscan2
- CDC20B | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57052783, COSV57054933; called by muse, mutect2, varscan2
- CDC5L | c.812_813insC p.K271Nfs*4 | Frame Shift Ins (INS) | VAF 22/152 reads (14%) | catalogued as COSV65176132; called by mutect2, pindel, varscan2
- CEP78 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99450977; called by muse, mutect2, varscan2
- CNOT9 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV99813860; called by muse, mutect2
- COL6A1 | c.1523G>A p.R508K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV62613406; called by muse, mutect2
- CSGALNACT1 | c.1442G>A p.C481Y | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760302332, COSV100175647; called by mutect2, varscan2
- CSNK2A1 | c.989A>T p.D330V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV53935286; called by muse, mutect2, varscan2
- DDX18 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99604838; called by muse, mutect2, varscan2
- DNAH1 | c.5698G>A p.V1900M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs375423663; called by mutect2, varscan2
- DNAH11 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100181054; called by muse, mutect2, varscan2
- ENTPD4 | c.357T>G p.D119E | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV62269135; called by muse, mutect2, varscan2
- EPPK1 | c.5354G>A p.R1785H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs189786019, COSV73261399, COSV73262293; called by muse, mutect2, varscan2
- FBN1 | c.7459G>C p.D2487H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57308093; called by muse, mutect2
- FBN1 | c.2755G>A p.G919R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57317664; called by muse, mutect2, varscan2
- GATB | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.792); catalogued as COSV56130618; called by muse, mutect2, varscan2
- GOLGA4 | c.4708C>T p.Q1570* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV62710906; called by mutect2, varscan2
- GRID2 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV56181925, COSV99944281; called by muse, mutect2, varscan2
- HIP1 | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV61186229; called by muse, mutect2, varscan2
- HPN | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52883848; called by muse, mutect2, varscan2
- HPR | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV57182937; called by muse, mutect2, varscan2
- IL16 | c.3389G>T p.G1130V (on ENST00000302987 / NM_172217.5; = p.G429V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57263907; called by muse, mutect2, varscan2
- IMPG1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1272470491, COSV64056736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ISCA2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53143474; called by muse, mutect2, varscan2
- JAKMIP2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1276650784, COSV54605362; called by muse, mutect2, varscan2
- KIF18B | c.1022C>G p.T341S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100192619; called by muse, varscan2
- KMT5B | c.914G>A p.C305Y | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58566267; called by muse, mutect2, varscan2
- KRT73 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs371740648, COSV59838302; called by mutect2, varscan2
- KRTAP4-3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1447672781, COSV66940862; called by muse, mutect2, varscan2
- LMTK2 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs1489268046, COSV99807854; called by muse, mutect2
- LRRC7 | c.805A>G p.M269V (on ENST00000651989 / NM_001370785.2; = p.M236V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs1223913802, COSV99230014; called by muse, mutect2, varscan2
- MAGEC1 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV99594799; called by muse, mutect2, varscan2
- MAN1A2 | c.1559C>G p.A520G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100740879, COSV100741078; called by muse, mutect2, varscan2
- MEGF8 | c.2972G>A p.R991Q (on ENST00000251268 / NM_001271938.2; = p.R924Q on NM_001410.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs1319984417, COSV52086147; called by muse, mutect2, varscan2
- MNDA | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV63740502, COSV63740869; called by muse, mutect2, varscan2
- NEMF | c.14T>A p.F5Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV100028146; called by muse, mutect2, varscan2
- NES | c.1639A>G p.K547E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV63961187; called by muse, mutect2, varscan2
- NUP205 | c.4344G>A p.M1448I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV99606540, COSV99607637; called by muse, mutect2
- OR11G2 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62132352; called by muse, mutect2, varscan2
- OR8B8 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60144660; called by muse, mutect2, varscan2
- OSGEP | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs375098598, COSV52831370; called by mutect2, varscan2
- PCDH11Y | c.1669G>A p.V557M (on ENST00000400457 / NM_032973.2; = p.V546M on NM_032971.3) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs754486741, COSV53081419; called by muse, mutect2, varscan2
- PCDHB4 | c.931_932insC p.I311Tfs*2 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | catalogued as COSV99522531; called by mutect2, pindel, varscan2
- PEG3 | c.1832G>T p.S611I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV55634745, COSV99686673; called by muse, mutect2, varscan2
- PLXNC1 | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs865899131, COSV51571846; called by muse, mutect2, varscan2
- POLG2 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs782061130, COSV56748391, COSV56749184; called by muse, mutect2, varscan2
- RASEF | c.1920+2T>A p.X640_splice | Splice Site (SNP) | VAF 46/135 reads (34%) | catalogued as COSV64587194; called by muse, mutect2, varscan2
- RIMKLB | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.975); catalogued as rs1565613517, COSV55237008; called by muse, mutect2, varscan2
- RSF1 | c.1760A>G p.K587R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV57844351; called by muse, mutect2, varscan2
- RYR1 | c.12358G>A p.E4120K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.778); catalogued as rs1333787732, COSV62100877; called by muse, varscan2
- SAMD9 | c.3281T>C p.I1094T | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV101180385; called by muse, mutect2
- SCN3A | c.4924C>A p.R1642S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99328646; called by muse, mutect2, varscan2
- SEMA3D | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV52394202; called by muse, mutect2
- SMR3A | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.528); catalogued as rs751646049, COSV56950284; called by mutect2, varscan2
- TAOK3 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV66825964; called by muse, mutect2, varscan2
- TCP11L1 | c.551T>G p.I184S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100178407; called by muse, mutect2, varscan2
- TRAPPC6A | c.389C>T p.A130V (on ENST00000585934 / NM_001270891.2; = p.A144V on NM_024108.3) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99135380; called by muse, mutect2, varscan2
- TRIT1 | c.1078C>A p.L360I | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57548466; called by muse, mutect2, varscan2
- UNC13C | c.5908C>A p.L1970M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52876452; called by muse, mutect2, varscan2
- UROD | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs750017956, COSV55800450; called by mutect2, varscan2
- USH2A | c.6595C>A p.L2199I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs773803465, COSV56374462; called by muse, mutect2, varscan2
- WWP1 | c.2179G>C p.D727H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55359472; called by muse, mutect2, varscan2
- ZNF35 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56076615; called by muse, mutect2, varscan2
- ZNF569 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565886241, COSV57595673; called by muse, mutect2, varscan2
- ZSWIM8 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1159464937, COSV67132671; called by muse, mutect2, varscan2
- CDCA2 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- EPHB1 | c.2884C>G p.Q962E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FAM81B | c.43dup p.R15Kfs*18 | Frame Shift Ins (INS) | VAF 17/101 reads (17%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.159G>A p.E53= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99663313; called by mutect2, varscan2
- ADRB3 | c.240C>T p.A80= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61462014; called by muse, mutect2, varscan2
- AP3S1 | c.486A>G p.V162= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV57474974; called by mutect2, varscan2
- COL4A1 | c.111C>A p.G37= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1166047992, COSV101011619; called by muse, mutect2, varscan2
- DAB1 | c.1656C>T p.S552= (on ENST00000371231; = p.S519= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs145981487; called by muse, mutect2, varscan2
- DCLK3 | c.1557C>T p.Y519= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs778712003, COSV69362566; called by mutect2, varscan2
- GALNT13 | c.123T>C p.S41= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV101224283; called by muse, mutect2, varscan2
- H1-2 | c.327G>A p.K109= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs765218240, COSV59190495, COSV59190892; called by muse, mutect2, varscan2
- HEPHL1 | c.1149T>C p.F383= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1395350273, COSV100244448; called by muse, mutect2, varscan2
- KCNQ2 | c.531C>T p.I177= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1170316817, COSV60434401; called by muse, mutect2, varscan2
- KMT2D | c.5778T>C p.L1926= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV56443379; called by muse, mutect2, varscan2
- KRTAP26-1 | c.54C>T p.T18= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1186496633, COSV62128864; called by muse, mutect2, varscan2
- OR52B4 | c.912G>A p.Q304= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101281565, COSV68768991; called by muse, mutect2, varscan2
- PCDHA13 | c.1353C>T p.N451= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs368758287, COSV56484020; called by muse, mutect2, varscan2
- PCDHA4 | c.1245C>A p.R415= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV63542122; called by muse, mutect2, varscan2
- PHF21A | c.408C>T p.L136= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs746891776, COSV57654288; called by muse, mutect2, varscan2
- PRRC2B | c.5697C>T p.F1899= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs767565858, COSV57645148; called by muse, mutect2, varscan2
- SYNE1 | c.23874C>T p.D7958= (on ENST00000367255 / NM_182961.4; = p.D7887= on NM_033071.3) | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs749141262, COSV54934128, COSV54992787; called by muse, mutect2, varscan2
- TCEAL2 | c.129C>T p.N43= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV61197413; called by muse, mutect2, varscan2
- TMEM14B | c.186C>T p.N62= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs754222551, COSV65355828, COSV65356058; called by mutect2, varscan2
- MFRP | chr11:119344733 C>T | 5'Flank (SNP) | VAF 6/20 reads (30%) | catalogued as rs201021366, COSV64128401; called by mutect2, varscan2
- MGAT4C | c.-2G>T | 5'UTR (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100153440; called by muse, mutect2, varscan2
- PSMB8 | chr6:32844281 C>G | 5'Flank (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99059099; called by muse, mutect2, varscan2
